Gene-level copy-number profile of tumor specimen REBC-ADK2-TTP1-A from REBC case REBC-ADK2, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADK2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 10487252-3010-4a72-a212-a60cdc8a4b4f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADK2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/560bf396-a174-4b00-b464-aaddc9485a20

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 171; copy number 2: 58,004; copy number 3: 132; copy number 4: 49; copy number 5: 12; copy number 6: 5; copy number 7: 6; copy number 8: 4; copy number 9: 2; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 30 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,682,108–246,691,821, 2 genes, copy number 9: AL591848.2, AL591848.1.
- chr2:197,569–266,398, 2 genes, copy number 5–18 (within-gene range 2–18): AC079779.1, SH3YL1.
- chr5:174,724,582–174,730,896, 1 gene, copy number 7: MSX2.
- chr15:76,993,359–77,083,984, 5 genes, copy number 5–7: PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2.
- chr16:11,555–38,321, 6 genes, copy number 5: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3.
- chr19:2,360,238–2,427,586, 2 genes, copy number 5: TMPRSS9, TIMM13.
- chr19:54,379,489–54,438,346, 5 genes, copy number 6–8: AC245884.4, TTYH1, AC245884.1, AC245884.9, AC245884.10.
- chr19:58,573,503–58,605,223, 4 genes, copy number 6 (within-gene range 2–6): CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr21:44,414,588–44,425,272, 1 gene, copy number 7 (within-gene range 7–8): TRPM2-AS.
- chr22:50,756,948–50,801,309, 2 genes, copy number 5: RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 171. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
